Surgical pathology report (de-identified scan), TCGA case TCGA-DB-5276, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-5276-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

Brain, left frontal No.1,2,3, biopsy: Grade 3 (of 4) oligoastrocytoma, astrocytic predominant (WHO, grade III).

Immunohistochemical stains were performed on paraffin embedded tissue using antibodies to GFAP, p53 and MIB-1. GFAP is positive in neoplastic cells with astrocytic morphology. p53 protein is overexpressed in the majority of tumor cells. MIB-1 labeling index is moderate. The findings support the above diagnosis.

ADDENDA:

1p and 19q FISH studies were performed on cells within paraffin sections from tumor. Two hybridizations were performed: one with a 19q probe/control 19p pair and one with a 1p probe/control 1q pair. The 19q and 1p probes mapped to the regions that are commonly deleted in gliomas. The 19q to 19p probe ratio was 1.00. The 1p to 1q probe ratio was 1.02. For both probes, the normal ratio is approximately 1. Any ratio less than 0.80 is consistent with deletion of the chromosomal region of interest.

There was no evidence of deletion of 1p or 19q. However, 60.1% of the cells had 3-4 copies of the 1p, 1q, 19p and 19q probes. Similar results have been observed in other glioma specimens with gain of chromosomes 1 and 19. The results may also be consistent with tumor tetraploidy or aneuploidy.

This test was developed and its performance characteristics determined by Laboratory Medicine and Pathology, [REDACTED] It has not been cleared or approved by the U.S. Food and Drug Administration, and is to

[page 2 of 2]
be used as an adjunct to existing clinical and pathological information. This test does not rule out other chromosome anomalies.

Preliminary Frozen Section Consultation:

Brain, left frontal No.1, biopsy: Atypical cells, consistent with infiltrating glioma.

Brain, left frontal No.2, biopsy: Diffuse glioma, favor astrocytoma. HOLD for definitive typing and grading.

Brain, left frontal No.3, excision:

Gross Description:

Tissue from brain (left frontal No.1 - 1.0 x 0.3 x 0.3 cm, No.2 - 1.2 x 0.7 x 0.2 cm, No.3 - 7.0 x 4.5 x 3.0 cm).

Block Summary:

Part A: left frontal craniotomy

1 Lt frontal brain

Part B: left frontal craniotomy

1 Lt frontal brain

Part C: left frontal craniotomy #3

1 Lt frontal brain

frontal brain

frontal brain

4 Lt frontal brain

5 Lt frontal brain

6 Lt frontal brain

7 Lt frontal brain

8 Lt frontal brain

9 Lt frontal brain

10 Lt frontal brain

END OF REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file 0c842617-d8ff-4898-a33b-4a78b4882464 (TCGA-DB-5276.B1F076D6-2B5C-43B9-8240-973C74EBF958.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).